Somatic mutation profile of tumor specimen 0DUXOY from CCDI case PBCLEX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 18.5 years (6,753 days).
Specimen 0DUXOY: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7a007a05-0fa7-47ec-8a4a-316b615a0ef6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUXNU (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/20f97b60-5834-4d4b-ab6c-ebab3dc9239c

The open-access MAF lists 41 somatic variants for this specimen: 26 protein-altering or splice-affecting, 7 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 7, Intron 4, 3'UTR 3, Nonsense Mutation 1, 5'UTR 1, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB1 | c.1639C>T p.R547C | Missense Mutation (SNP) | VAF 177/901 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs199852575, COSV55948242; called by muse, mutect2, varscan2
- CD300E | c.245C>T p.P82L | Missense Mutation (SNP) | VAF 56/690 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as rs148103699; called by muse, mutect2
- CNOT4 | c.289C>T p.R97C | Missense Mutation (SNP) | VAF 34/887 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV59655715; called by muse, mutect2
- FRMD5 | c.1151G>A p.R384Q | Missense Mutation (SNP) | VAF 197/614 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs367941749; called by muse, mutect2, varscan2
- LRRK2 | c.5019G>T p.L1673F | Missense Mutation (SNP) | VAF 77/567 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1323591086, COSV100109070, COSV100109697; called by muse, mutect2, varscan2
- MUC15 | c.374C>G p.P125R | Missense Mutation (SNP) | VAF 221/864 reads (26%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV55554422; called by muse, mutect2, varscan2
- RNF128 | c.31del p.W11Gfs*4 | Frame Shift Del (DEL) | VAF 162/467 reads (35%) | catalogued as rs757038390; called by mutect2, varscan2
- SLC30A8 | c.524C>T p.A175V | Missense Mutation (SNP) | VAF 109/1371 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.269); catalogued as rs748727258, COSV101438826, COSV69976410; called by muse, mutect2
- SULT2B1 | c.454G>A p.V152I (on ENST00000201586 / NM_177973.2; = p.V137I on NM_004605.2) | Missense Mutation (SNP) | VAF 99/872 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.143); catalogued as rs1432402312; called by muse, mutect2, varscan2
- TUBE1 | c.766G>C p.D256H | Missense Mutation (SNP) | VAF 113/821 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.713); catalogued as rs1554315976; called by muse, mutect2, varscan2
- WDR90 | c.4165G>A p.E1389K | Missense Mutation (SNP) | VAF 192/679 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs745634832, COSV53472386; called by muse, mutect2, varscan2
- A2M | c.88C>A p.Q30K | Missense Mutation (SNP) | VAF 66/874 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.014); called by muse, mutect2
- C12orf29 | c.115A>G p.T39A | Missense Mutation (SNP) | VAF 85/754 reads (11%) | SIFT tolerated (0.61); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- CC2D2A | c.1030T>C p.F344L | Missense Mutation (SNP) | VAF 98/1053 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CHKA | c.369G>A p.M123I | Missense Mutation (SNP) | VAF 40/768 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.07); called by muse, mutect2
- CPN2 | c.1504C>A p.L502M | Missense Mutation (SNP) | VAF 56/473 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- HIF1AN | c.701A>G p.H234R | Missense Mutation (SNP) | VAF 82/1104 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MAP2 | c.1499C>A p.P500H | Missense Mutation (SNP) | VAF 241/1151 reads (21%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- MEGF8 | c.3204_3207dup p.A1070Ifs*6 (on ENST00000251268 / NM_001271938.2; = p.A1003Ifs*6 on NM_001410.3) | Frame Shift Ins (INS) | VAF 62/688 reads (9%) | called by mutect2, pindel
- OR10X1 | c.264C>A p.C88* | Nonsense Mutation (SNP) | VAF 122/843 reads (14%) | called by muse, mutect2
- SETSIP | c.721C>A p.Q241K | Missense Mutation (SNP) | VAF 132/918 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by mutect2, varscan2
- SLC13A1 | c.1759C>G p.P587A | Missense Mutation (SNP) | VAF 129/735 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- SPHKAP | c.3618C>A p.S1206R | Missense Mutation (SNP) | VAF 319/972 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TMEM248 | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 54/1183 reads (5%) | SIFT tolerated (0.45); PolyPhen benign (0.053); called by muse, mutect2
- TRAF4 | c.269G>T p.C90F | Missense Mutation (SNP) | VAF 438/1361 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- WDR41 | c.1091C>G p.T364R | Missense Mutation (SNP) | VAF 113/961 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- CHAT | c.1032C>T p.D344= | Silent (SNP) | VAF 186/1470 reads (13%) | catalogued as rs145203976; ClinVar: likely benign; called by muse, mutect2, varscan2
- CLIP2 | c.1755C>T p.N585= | Silent (SNP) | VAF 34/1226 reads (3%) | catalogued as rs529112547; called by muse, mutect2
- DIP2A | c.3240C>T p.L1080= | Silent (SNP) | VAF 195/1654 reads (12%) | catalogued as rs372387821; called by muse, mutect2, varscan2
- IGSF9 | c.1359C>T p.T453= (on ENST00000368094 / NM_001135050.2; = p.T437= on NM_020789.4) | Silent (SNP) | VAF 90/729 reads (12%) | catalogued as COSV63641685; called by muse, mutect2, varscan2
- KRT81 | c.30C>T p.R10= | Silent (SNP) | VAF 190/1591 reads (12%) | catalogued as rs1326820632; called by muse, mutect2, varscan2
- NEBL | c.276C>A p.T92= | Silent (SNP) | VAF 68/729 reads (9%) | called by muse, mutect2
- VSIR | c.111G>A p.T37= | Silent (SNP) | VAF 87/802 reads (11%) | catalogued as rs370155250; called by muse, mutect2, varscan2
- ANAPC11 | c.*73A>G | 3'UTR (SNP) | VAF 238/1313 reads (18%) | called by muse, mutect2, varscan2
- BAX | c.475-55G>T | Intron (SNP) | VAF 127/1086 reads (12%) | called by muse, mutect2, varscan2
- BBOF1 | c.*81A>T | 3'UTR (SNP) | VAF 25/757 reads (3%) | called by muse, mutect2
- CCPG1 | c.*4006C>T | 3'UTR (SNP) | VAF 20/144 reads (14%) | called by muse, mutect2, varscan2
- FRYL | c.8395-82T>G | Intron (SNP) | VAF 12/396 reads (3%) | called by muse, mutect2
- KLK11 | c.294-63C>T | Intron (SNP) | VAF 117/1010 reads (12%) | called by muse, mutect2, varscan2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 28/240 reads (12%) | called by muse, varscan2
- USP31 | c.2176+36G>A | Intron (SNP) | VAF 46/358 reads (13%) | catalogued as rs373237986; called by muse, mutect2, varscan2
